Somatic mutation profile of tumor specimen TCGA-ZB-A961-01A (aliquot TCGA-ZB-A961-01A-11D-A428-09) from TCGA case TCGA-ZB-A961, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Thymoma, type A, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 69.6 years (25,419 days).
Specimen TCGA-ZB-A961-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48320c6d-792e-4f76-9b53-f4bf96cc1223.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A961-10A (Blood Derived Normal), aliquot TCGA-ZB-A961-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6976a632-1dde-45ba-ac97-58c6a7edbbcc

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Frame Shift Del 1, In Frame Del 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC141 | c.1762G>C p.E588Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV55371515; called by muse, mutect2, varscan2
- IMPA1 | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1233065614; called by muse, mutect2, varscan2
- MAGEB18 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100305660, COSV57463393; called by muse, mutect2, varscan2
- SCN1A | c.1211T>C p.V404A | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57680480; called by muse, mutect2, varscan2
- SSTR3 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.929); catalogued as rs1293416143, COSV60729043; called by mutect2, varscan2
- ARHGEF12 | c.3040G>T p.D1014Y | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CD276 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- CHD9 | c.2001T>G p.N667K | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLIP2 | c.2675C>G p.S892W | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSPA4 | c.1796A>C p.E599A | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- LBH | c.191T>C p.I64T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- LGSN | c.445C>A p.L149I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- PIK3C3 | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCXD2 | c.40_56del p.G14Qfs*39 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- PROS1 | c.1816G>C p.V606L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- RAB29 | c.473A>G p.E158G | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- RB1CC1 | c.3056_3070del p.K1019_Q1023del | In Frame Del (DEL) | VAF 3/34 reads (9%) | called by pindel, varscan2*
- SPHKAP | c.4856G>A p.C1619Y (on ENST00000392056 / NM_001142644.2; = p.C1590Y on NM_030623.3) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ACOX1 | c.1080T>G p.G360= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- BIRC3 | c.993C>A p.I331= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV54820628; called by muse, mutect2, varscan2
- MIGA1 | c.1524T>C p.S508= | Silent (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- STXBP5 | c.3369G>A p.A1123= (on ENST00000321680 / NM_001127715.2; = p.A1087= on NM_139244.4) | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs757465735; called by mutect2, varscan2
- TTI1 | c.93G>A p.E31= | Silent (SNP) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- TRPM3 | c.184-256673T>A | Intron (SNP) | VAF 9/27 reads (33%) | called by muse, varscan2
